CCDI case PBCIAX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/00bd0b31-bf64-4489-98a1-0e0780e14056

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Hemangioendothelioma, malignant: ICD-O-3 morphology code: 9130/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 21.5 years (7,837 days).

Biospecimens (3 samples)
- Samples 0DT9MP, 0DT9NL (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9N8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
